Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MS, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MS-01A (Primary Tumor).

[page 1 of 2]
Specimen:

Procedure:

Accessioned:

Reported:

Submitting Phys:

Patient:

Medical Record #:

DOB/Age/Sex:

Location/Client:

Account #:

(Age: F

Surgical Pathology Report

Final Diagnosis

ADRENAL GLAND, RIGHT, ADRENALECTOMY:
- PHEOCHROMOCYTOMA.

SIZE OF TUMOR:

- 3 X 2.8 X 2.6 CM.

WEIGHT OF ADRENAL GLAND:

- 29 GRAMS.

EXTENT OF TUMOR:

- TUMOR IS CONFINED TO THE ADRENAL GLAND.

MARGINS OF RESECTION:

- MARGINS ARE FREE OF TUMOR.

LYMPH NODES:

- NUMBER EXAMINED: 0
- NUMBER POSITIVE: 0

ADDITIONAL TUMOR FEATURES:

- BLOOD VESSEL INVASION: NOT IDENTIFIED
- LYMPH VESSEL INVASION: NOT IDENTIFIED.
- NUCLEAR ATYPIA: MARKED.
- NECROSIS: ABSENT.

COMMENT: There is no evidence of adrenal medullary hyperplasia or of features reported to be associated with von Hippel-Lindau disease (Koch et al., Endocr Pathol 13, 17-27, 2002).

ANCILLARY STUDIES:

- IMMUNOHISTOCHEMICAL STUDIES ARE PERFORMED, THE RESULTS ARE AS FOLLOWS:
- Ki-67/Mib1 - AVERAGE 13 LABELED TUMOR CELLS PER 20X FIELD. LABELING IS ALSO PROMINENT IN ENDOTHELIAL CELLS AND VASCULAR SMOOTH MUSCLE WITHIN THE TUMOR.
- p27Kip1 - POSITIVE IN TUMOR CELLS.
- S100 - POSITIVE IN SPARSE SUSTENTACULAR CELLS PRESENT WITHIN THE TUMOR
- SMOOTH MUSCLE ACTIN - PROMINENT IN NUMEROUS BLOOD VESSELS WITHIN THE

TUMOR

Intradepartmental consultation with Dr.

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated)

[page 2 of 2]
of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Clinical History
Pheochromocytoma.

Pre-Operative Diagnosis
(Not Provided)

Post-Operative Diagnosis
(Not Provided)

Gross Description

A. RIGHT ADRENAL GLAND (FRESH): The specimen, labeled with the patient's name and medical record number, is an adrenal gland weighing 29 grams and measuring 5.5 x 5.5 x 2 cm. The specimen is serially sectioned to reveal of a 3 x 2.8 x 2.6 cm tan-brown, soft friable mass in the medulla. The mass is well-circumscribed and does not extend beyond the adrenal gland. The remaining adrenal gland away from the mass appears unremarkable with a golden yellow cortex and a dull-gray medulla. The specimen is represented, including entire tumor, as follows:

SECTION CODE

A1-4: MASS.
A5: NORMAL-APPEARING ADRENAL TISSUE.
A6-9: REMAINDER OF THE TUMOR

Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by Department of Pathology. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Metastatic/Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file da020c3f-33c0-4f1b-b8e8-f6f2fc40223d (TCGA-SR-A6MS.A37F899E-D942-455B-B90F-CE52A66894E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).